Surgical pathology report (de-identified scan), TCGA case TCGA-23-2649, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-2649-01A (Primary Tumor).

[page 1 of 11]
SURGICAL PATHOLOGY REPORT

***** Addendum - Please See End of Report *****

Reason for Addendum #1: Additional sections or studies

Reason for Addendum #2: Additional studies/stains/opinion(s)

DIAGNOSIS:**A. OMENTUM, PARTIAL OMENTECTOMY:**

- Metastatic mullerian-derived carcinoma

B. FALLOPIAN TUBE AND OVARY, LEFT, SALPINGO-OOPHORECTOMY:

- Primary ovarian carcinoma, high-grade (3/3) with undifferentiated and serous features
- Ovary is subtotally replaced by carcinoma
- Tumor is about 6.0 cm in maximum dimension
- Serosal surface of ovary is also involved by tumor
- Lymphovascular invasion by carcinoma is present
- Tumor also involves the serosal surface of the fallopian tube
- Paraovarian and paratubal ligamentous soft tissues show secondary involvement by carcinoma
- Fimbriated end of fallopian tube also shows a small focus of carcinoma
- Fallopian tube also shows foci of epithelial hyperplasia
- Paratubal cyst lined by benign serous epithelium (hydatid of Morgagni)

C. SOFT TISSUE, RIGHT SIDE WALL, "TUMOR", EXCISION:

- Metastatic mullerian-derived carcinoma

D. FALLOPIAN TUBE AND OVARY, RIGHT, SALPINGO-OOPHORECTOMY:

- Ovary with partial replacement by invasive carcinoma, mixed undifferentiated and serous types, possibly metastatic
- Carcinoma also extensively involves the serosal surface of the ovary
- Secondary involvement of paraovarian and paratubal soft tissues by carcinoma
- Fallopian tube shows extensive involvement by carcinoma; tumor is present within mucosa, stroma of plicae and muscular wall
- Extensive lymphovascular invasion by tumor in virtually all involved sites
- Ovary also shows cystic epithelial inclusions
- Paratubal cystic Walthard rest

E. UTERUS, TOTAL ABDOMINAL HYSTERECTOMY:

- High-grade mullerian-derived carcinoma with mixed serous and undifferentiated features, favor metastatic, involving:
- Parametrial soft tissues
- Uterine serosa

[page 2 of 11]
-
- Muscular wall of uterus (4 cm diameter mass of tumor in outer wall of anterior uterine corpus)
- Stroma and muscular wall of cervix
- Lymphatic and blood vessel distributed throughout uterus, including uterine cervix, lower uterine segment, corpus and fundus, and within parametrium
- Endometrial mucosa, predominantly within lymphatic spaces
- Other findings include:
- Endometrium with weakly proliferative to proliferative features
- Uterine leiomyoma
- Cervix with chronic and mild acute inflammation, reactive squamous atypia, squamous metaplasia, reserve cell hyperplasia, microglandular endocervical hyperplasia and some cystically dilated endocervical glands
- Detached aggregates of tumor in cervical/endocervical canal

F. [SOFT TISSUE], CUL-DE-SAC, "TUMOR", EXCISION:

- Metastatic mullerian-derived carcinoma

G. [SOFT TISSUE], LEFT SIDE WALL, EXCISION:

- Metastatic mullerian-derived carcinoma

H. VERMIFORM APPENDIX, APPENDECTOMY:

- Metastatic mullerian-derived carcinoma involving mesosalpinx, serosa and subserosa of appendix and outer muscular wall of appendix and regional lymphovascular spaces
- Appendix also shows partial fibrous luminal obliteration (so-called appendiceal neuroma) and adhesions

I. SKIN AND SUBCUTANEOUS TISSUE, UMBILICUS, BIOPSY:

- Microscopic focus of metastatic mullerian-derived carcinoma, crushed and poorly preserved
- Fibrosis

J. TCGA STUDY A, B AND D:

- Mullerian-derived carcinoma embedded in block J1 with about 80% to 85% tumor cell nuclei and less than 20% tumor cell necrosis
- Mullerian-derived carcinoma embedded in block J2 with about 25% to 30% tumor nuclei and less than 10% tumor cell necrosis; some non-neoplastic ovarian tissue is also present in sections from block J2
- Mullerian-derived carcinoma embedded in block J3 with about 50% tumor cell nuclei and less than 20% tumor cell necrosis

SYNOPSIS REPORT:

Applies To:

A : OMENTUM

B : LEFT TUBE AND OVARY

C : RT SIDE WALL TUMOR

D : RIGHT TUBE AND OVARY

E : UTERUS & CERVIX

F : CULDESAC TUMOR

[page 3 of 11]
G : LT SIDE WALL TUMOR
H : APPENDIX
I : UMBILICUS

Macroscopic

Specimen Type:	Left and right ovaries Left and right fallopian tubes Uterus Omentum Peritoneum
Other Organs Present:	Vermiform appendix; skin of umbilicus
Procedure:	Right salpingo-oophorectomy Left salpingo-oophorectomy Hysterectomy Omentectomy Peritoneal biopsies Appendectomy; biopsy of skin of umbilicus
Specimen Integrity, right ovary:	Intact
Specimen Integrity, left ovary:	Intact

Microscopic

Histologic Type:	Mixed epithelial, carcinoma Components: Serous (25%) and undifferentiated (75%)
Histologic Grade:	G3: Poorly differentiated
Primary tumor site:	Bilateral ovarian involvement, primary site cannot be determined Comment(s): Tumor in left ovary appears to be primary in that site; tumor in right ovary might be metastatic or represent a second primary neoplasm
Tumor Size:	Right ovarian tumor, greatest dimension: 2.5cm Left ovarian tumor, greatest dimension: 6cm
Ovarian surface involvement:	Present
Summary of Organs/Tissues Microscopically Involved by Tumor:	Both ovaries Fallopian tube(s) Omentum Uterus Peritoneum Vermiform appendix; umbilicus
Lymphovascular Invasion:	Present

Primary Tumor (pT):	pT3c : Macroscopic peritoneal metastasis beyond pelvis more than 2 cm in greatest dimension and/or regional lymph node metastasis
Regional Lymph Nodes (pN):	pNX: Cannot be assessed
Number of lymph nodes identified:	0
Number of lymph nodes involved:	0

Comment(s)

[page 4 of 11]
HISTORY:

Ovarian cancer.

MICROSCOPIC FINDINGS:

See diagnosis.

SPECIAL STUDIES:

Additional H&E-stained short step sections (E3 x1, E4 x1, E6 x1, E7 x1, E9 x1, I1 x1)

IMMUNOHISTOCHEMICAL

Study//Antibody	Block	Result
S-100	H1	In the tip of the appendix where there is luminal obliteration, there are aggregates of S-100 positive spindle cells consistent with so-called appendiceal neuroma.

GROSS:

A. OMENTUM

Labeled with the patient's name, labeled "omentum", and received in formalin are two portions of omentum measuring 18.0 x 6.5 x 2.5 cm, and 7.0 x 3.0 x 2.0 cm.

There are multiple tan firm tumor nodules involving the omentum. The tumor nodules range from 0.1 to 2.5 cm.

Representative sections are submitted.

Slide key:

A1. 1

A2. 1

B. LEFT TUBE AND OVARY

Labeled with the patient's name, labeled "left tube and ovary", and received fresh in the Operating Room for intraoperative frozen section and subsequently fixed in formalin is about a 53.7 gram salpingo-oophorectomy specimen. The ovary was incised at the time of intraoperative consultation and now in the partially collapsed state is about 6.0 x 5.5 x 4.0 cm. The fimbriated fallopian tube is about 5.0 cm long, ranges from 0.5 to 0.7 cm in diameter and has a maximum luminal diameter of 0.2 cm.

The ovary is virtually replaced by a cystic and solid neoplasm that is about 6.0 cm in maximum dimension. The cystic component of the neoplasm accounts for about 40% of the tumor volume and is multiloculated. The cystic loculations range from about 0.2 to 3.5 cm in maximum dimension and contain clear yellow fluid. Some of cystic loculations are lined by a smooth tan tissue and some are lined by papillated tan tissue. The solid component of the neoplasm is composed of firm, white-yellow tissue. The capsule of the ovary is intact, but the similar-appearing tumor also involves the serosal surface of the ovary. The ligamentous adnexal soft tissue adjacent to the ovary and fallopian tube show nodular and plaque-like aggregates of semifirm tan tumor ranging from about 0.1 to 1.0 cm in diameter. There is also about a 0.2 cm nodular aggregate of similar-appearing tan tumor on the serosal surface of the fallopian tube.

There is about a 0.3 cm diameter fluid-filled thin-walled paratubal cyst. Adhesions on the adnexa are also noted.

A gross photograph of the specimen is obtained.

[page 5 of 11]
[REDACTED]

Representative sections are submitted.

Slide key:

- B1. Remnant of frozen section - 1
- B2-B6. Ovary with tumor - 1 each
- B7. Ovary with tumor - 1 each
- B8. Fallopian tube with focal serosal tumor and paratubal tumor - 4
- B9, B10. Adnexal ligaments with tumor - 3 each
- B11-B13. Ovary with tumor - 1 each

C. RIGHT SIDEWALL TUMOR

Labeled with the patient's name, labeled "right sidewall tumor", and received in formalin are four fragments of yellow-tan soft tissue ranging from about 0.2 to 6.0 cm in maximum dimension and amounting in aggregate to about 7.5 x 6.0 x 2.7 cm.

All the tissue fragments show extensive involvement by nodular and plaque like aggregates of firm tan tumor. The individual tumor nodules range from about 0.1 to 0.5 cm in maximum dimension.

Representative sections are submitted.

Slide key:

- C1-C3. Largest tissue fragment with tumor - 1 each
- C4. Second largest tissue fragment with tumor - 2
- C5. Smaller tissue fragment with tumor - 1 each
- C6. One tumor nodule - 1

D. RIGHT TUBE AND OVARY

Labeled with the patient's name, labeled "right tube and ovary", and received fresh in the Operating Room for [REDACTED] study, and subsequently fixed in formalin is a 26.7 gram salpingo-oophorectomy specimen. The ovary was incised at the time of intraoperative consultation. The ovary is about 4.5 x 3.5 x 2.5 cm. The adjacent fimbriated fallopian tube is 5.0 cm long and ranges from 0.6 to 1.0 cm in diameter with a maximum luminal diameter of about 0.3 cm.

The ovary is subtotally replaced by firm white-yellow tumor. The tumor within the ovary is about 2.5 cm in maximum dimension. There are also several nodular and plaque like aggregates of firm tan-white tumor on the serosal surface of the ovary. The latter of which ranges from about 0.2 to 1.0 cm in diameter. The fallopian tube appears to be partially replaced by tan-white semisoft to firmer tumor. Tumor in the fallopian tube involves the mucosa, wall and focally obstructs the lumen of the fallopian tube.

Attached to the fallopian tube, there is a thin-walled translucent fluid-filled paratubal cyst that is about 0.2 cm in diameter.

A photograph of the specimen is obtained.

Representative sections are submitted.

Slide key:

- D1-D7. Ovary with tumor - 1 each
- D8. Fallopian tube with tumor - 4

E. UTERUS AND CERVIX

Labeled with the patient's name, labeled "uterus and cervix", and received in formalin is a previously incised 95 gram total hysterectomy specimen. The uterus is about 9.0 x 5.0 x 4.5 cm in greatest overall dimensions. The cervical portion of the uterus alone is about 3.5 cm long and up to 3.5 cm in width. The

[page 6 of 11]
endometrial cavity is about 3.5 cm long and up to 2.0 cm in width. The endometrial mucosa ranges from about 0.1 to 0.3 cm in thickness. The muscular uterine wall ranges from about 1.5 to 2.5 cm in thickness. Attached to the cervix, there is an up to 0.3 cm long cuff of vaginal mucosa.

The serosal surface of the uterus and outer aspect of the cervix are partially coated by nodular and plaque-like aggregates of firm tan tumor. The tumor deposits on the external aspect of the uterus and cervix range from about 0.5 to 1.5 cm in maximum dimension. Cut sections of the anterior uterine corpus reveal a mass of tan-white tumor that is mostly firm but shows areas of softening that involve the muscular wall of the uterus. The intramural portion of the tumor is about 4.0 cm in maximum dimension. There are also a few areas of induration of the endometrial mucosa which are tan-white and up to 0.3 cm in diameter that may represent tumor. Most of the tumor in the uterus and cervix appear to represent metastatic tumor.

There is a well-circumscribed 1.3 cm diameter intramural leiomyoma in the anterior lower uterine segment that is composed of firm solid tan-white whorled tissue without grossly evident areas of hemorrhage or necrosis. Except for the areas of induration, noted above the endometrial mucosa is grossly unremarkable. The cervix shows a few mucus-filled cysts, the largest of which is about 0.3 cm in diameter. Representative sections are submitted.

Slide key:

- E1. Anterior cervix and vaginal cuff - 1
- E2. Anterior cervix - 1
- E3. Posterior cervix with paracervical tumor - 1
- E4. Anterior lower uterine segment with leiomyoma - 1
- E5. Posterior lower uterine segment with serosal tumor - 1
- E6. Posterior lower uterine corpus with serosal tumor and area of induration of endometrial mucosa - 1
- E7, E8. Anterior uterine corpus, bisected, with tumor mass involving outer muscular wall of uterus - 1 each
- E9, E10. Anterior uterine corpus, bisected with tumor involving wall of uterine serosa - 1 each
- E11. Posterior uterine corpus - 1
- E12. Posterior uterine corpus - 1

F. CUL-DE-SAC TUMOR

Labeled with the patient's name, labeled "cul-de-sac tumor", and received in formalin is a 4.5 x 3.2 x 2.5 cm portion of tissue.

The specimen is virtually replaced by firm tan-white tumor. Focal hemorrhage is also noted. No uninvolved tissue is evident on gross inspection of the specimen.

Representative sections are submitted.

Slide key:

- F1-F3. Tumor - 1 each

G. LEFT SIDEWALL

Labeled with the patient's name, labeled "left sidewall", and received in formalin is about a 7.0 x 2.5 x 0.8 cm portion of tan-yellow soft tissue.

About 90% of the specimen is replaced by nodular and plaque-like aggregates of firm tan to tan-white tumor. The tumor deposits range from about 0.2 to 5.5 cm in maximum dimensions.

Representative sections are submitted.

Slide key:

[page 7 of 11]
[REDACTED]

G1-G3. Soft tissue with tumor - 1 each

H. APPENDIX

Labeled with the patient's name, labeled "appendix", and received in formalin is a 5.0 cm long vermiform appendix that ranges from about 0.4 to 0.6 cm in diameter. There is attached fatty mesoappendix that is up to 1.5 cm in width.

The mesoappendix and serosal surfaces of the appendix are partly coated by nodular and plaque-like aggregates of firm tan-white tumor. The tumor deposits range from about 0.3 to 1.2 cm in maximum dimension. No gross tumor is seen at the proximal resection margin.

The lumen of the appendix in the proximal segment is patent. In the tip of the appendix the lumen is obliterated by yellow-white fibroadipose tissue. No fecalith or perforations are identified.

Ink key: proximal surgical margin - blue.

Representative sections are submitted.

Slide key:

H1. Proximal, mid portion and tip of appendix and mesoappendix with tumor - 3

I. UMBILICUS

Labeled with the patient's name, labeled "umbilicus", and received in formalin are two portions of tan fibrous tissue, about 0.9 x 0.5 x 0.5 cm and 0.6 x 0.4 x 0.3 cm.

No gross tumor is seen.

Entirely submitted.

Slide key:

I1. 2 each

J. [REDACTED]-C

Labeled with the patient's name, labeled [REDACTED] and received in formalin in three separate cassettes labeled [REDACTED] "D" are six portions of tissue with tan tumor, two in each cassette. The tumor fragments in cassette [REDACTED] "A" are about 0.7 x 0.5 x 0.3 cm and 0.7 x 0.5 x 0.4 cm. The two fragments of tissue in cassette [REDACTED] are about 1.0 x 0.4 x 0.3 cm and 7.0 x 0.6 x 0.4 cm. The last two portions of tissue which are present in cassette [REDACTED] are each about 0.6 x 0.4 x 0.4 cm. The tissues in these cassettes apparently represent samples of tumor obtained from specimens A, B and D. [REDACTED] does not specifically state in her operative consultation or operative call, which cassette represents tissue from specimen A versus B versus D.

Entirely submitted.

[REDACTED]

INTRAOPERATIVE CONSULTATION:
FROZEN SECTION B:

[page 8 of 11]
- Left ovary: high grade carcinoma, favor mullerian origin
- [REDACTED]
- Tissue taken for [REDACTED] and Oncotech

OPERATIVE CALL:
SPECIMENS A AND D:

- Tissue taken for [REDACTED]

ADDENDUM:

RESULTS OF ADDITIONAL IMMUNOHISTOCHEMICAL STUDIES:

Study / Antibody	Block	Result
Estrogen receptor	B3	About 70% of the neoplastic cells exhibit positive nuclear staining. The staining intensity ranges from 1 to 3 out of 3.
Progesterone receptor	B3	Less than 10% of the neoplastic cells exhibit positive nuclear staining. The staining intensity ranges fro 1 to 3 out of 3.
Epidermal growth factor receptor	B13	Few (less than 3%) of the neoplastic cells exhibit positive staining.

[page 9 of 11]
FLUORESCENCE IN SITU HYBRIDIZATION (FISH) for EGFR in OVARY

Tissue Block:

RESULTS: POLYSOMY of chromosome 7 (See note below)

Number of cells evaluated: 40

INTERPRETATION:

Fluorescence in situ hybridization (FISH) analysis on a ovary tumor sample from this patient with Abbott Molecular probes specific for the centromere of chromosome 7 (control probe) and the short arm (EGFR-7p12) of chromosome 7 was performed.

These studies showed polysomy of chromosome 7 in 65% of the nuclei examined. In ovary tumors this signal pattern correlates with an amplified EGFR signal pattern.

NOTE:

1. Samples are considered positive in ovary if the EGFR to CEP 7 signal ratio is ≥ 2.0 in $\geq 10\%$ of analyzed cells or tumors with four or more copies of the EGFR gene in $\geq 40\%$ of the cells (high polysomy).
2. Samples are considered inconclusive, requiring consult with the pathologist, in ovary if the EGFR to CEP 7 signal ratio is ≥ 2.0 in $<10\%$ of analyzed cells or when four or more copies of the EGFR gene in $< 40\%$ of the cells.
-

[page 10 of 11]
HER-2 gene Amplification by Fluorescent in situ hybridization (FISH)
(Path Vysion, Abbott Molecular)

BLOCK: B13

RESULTS: Her2/neu gene signal pattern: Not amplified

Ratio of Her-2/neu over chromosome 17 is: 1.4

Average Her-2/neu gene copies per tumor cell: 3.5

Average Chromosome 17 centromeres per tumor cell: 2.2

Number of cells analyzed: 20

INTERPRETATION:

Fluorescence in situ hybridization (FISH) analysis on a breast tumor sample from this patient with Abbott probes specific for the centromere of chromosome 17 (control probe) and HER-2 (17q12) was performed and scored by a technologist.

NOTES:

A ratio of greater than or equal to 2.2 is considered amplified.

A ratio of less than or equal to 1.8 is considered not amplified.

A ratio between 1.8 and 2.2 is considered "equivocal" and the results must be interpreted with caution.

The nuclei counted in these studies were within the region selected by a pathologist and were analyzed. Specimens were fixed in 10% neutral buffered formalin. An adequate number tumor cells were available for analysis. Concurrently run positive controls gave expected results.

[page 11 of 11]
[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 46ec7261-6763-4a03-98de-f4799531f1b3 (TCGA-23-2649.7A0BD8E4-1C7B-4BBC-BDDC-E06902FC4DB5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).